Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8483, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8483-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED] Case ID	Gross Description	Microscopic Description	Diagnosis Details
[REDACTED]	Stomach with saucer-like tumor up to 9.5 cm in size, with invasion into the perigastric fatty tissue. In the fatty tissue there are dense hyperemic lymph nodes. Omentum is hyperemic.	Gastric adenocarcinoma, intestinal type, G-2. Invasion into the perigastric fat. There are foci of tumor growth in the fat tissue of greater and lesser omentum. For of twelve examined lymph nodes demonstrated metastasis.	Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 2 of 3]
Comments	Formatted Path Report
Original records say N1.	STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Antrum Tumor size: 0 x 0 x 9.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, intestinal type Histologic grade: Moderately differentiated Tumor extent: Subserosa Lymph nodes: 4/15 positive for metastasis (Greater and lesser curvature 4/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

	ID

[page 3 of 3]
Excision date

Laterality

Source: NCI Genomic Data Commons file 16ea9623-bbd8-4608-a356-3d2f91d0bbb0 (TCGA-BR-8483.5905E95B-F7A0-4A2A-AE1E-C7ED21309DB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).